Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0SW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0SW-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 1/27/11 fur

SURGICAL PATHOLOGY REPORT

Name:
Sex: F
Age:
Doctor:
Room No:

Lab No.:
Date Collected:
Date Received:
M.R. No.:
Hosp.No:

CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS: Right Breast Cancer

POSTOPERATIVE DIAGNOSIS:

OPERATION: Lumpectomy Right Breast, Right Sentinel Lymph Node Biopsy

SPECIMEN: A) Right Breast Mass – 1 Short Anterior – 2 Short Superior – 1 Long Medial, B) Sentinel Node #1 F.S., C) Sentinel Node #2 F.S., D) Axillary Contents E) Gross Margin Additional Inferior Margin Right Breast Mass suture New Inferior Margin

FROZEN SECTION DIAGNOSIS:

A) GROSS MARGINS: VERY CLOSE (LESS THAN 1 MM), TO INFERIOR MARGIN.

B) SENT LYMPH NODE #1 - POSITIVE FOR METASTATIC CARCINOMA.

C) SENT LYMPH NODE #2 – POSITIVE FOR METASTATIC CARCINOMA.

RECEIVED

[page 2 of 2]
PAGE 2

Name:
Sex: F
Age:
Doctor:
Room No:

Lab No.:
Date Collected:
Date Received:
M.R. No.:
Hosp.No:

FINAL DIAGNOSIS:

- A) RIGHT BREAST TISSUE - POORLY DIFFERENTIATED
INFILTRATING DUCTAL CARCINOMA.
SCARFF-BLOOM-RICHARDSON GRADE III/III.
THE TUMOR MEASURES 3.5 CM. IN MAXIMUM DIMENSION AND
FOCALLY CLOSE TO ANTERIOR AND POSTERIOR SURGICAL
MARGINS, (LESS THAN 1 MM.), SLIDES #5 AND #6.
THE REMAINING SURGICAL MARGINS ARE FREE OF THE
LESION.
LYMPHOVASCULAR INVASION IS IDENTIFIED.
MICROCALCIFICATIONS ARE IDENTIFIED.
- B) SENTINEL LYMPH NODE - ONE (1) POSITIVE LYMPH NODE, (1/1).
- C) SENTINEL LYMPH NODE - ONE (1) POSITIVE LYMPH NODE, (1/1).
- D) AXILLARY CONTENTS - 2 OF 13 LYMPH NODES ARE POSITIVE FOR
MALIGNANCY, (2/13).
- E) ADDITIONAL RIGHT BREAST TISSUE - NEGATIVE FOR
MALIGNANCY.

PTNM CLASSIFICATION: PIIIa, T2, N2, MX.

PATHOLOGIST

Source: NCI Genomic Data Commons file c64b36e8-9d0d-428c-b44c-3396b998f997 (TCGA-A2-A0SW.8401DFCF-8793-461A-B17E-E6584CE2423B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).